Somatic mutation profile of tumor specimen TCGA-BI-A20A-01A (aliquot TCGA-BI-A20A-01A-11D-A14W-08) from TCGA case TCGA-BI-A20A, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; AJCC pathologic stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 49.9 years (18,215 days).
Specimen TCGA-BI-A20A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b38f291-7392-4b7e-aac2-a2d381c02a4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BI-A20A-10A (Blood Derived Normal), aliquot TCGA-BI-A20A-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b76d76bc-1b74-4698-afb2-7d6b77fa3622

The open-access MAF lists 54 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 11, Nonsense Mutation 4, Frame Shift Ins 1, Intron 1, Frame Shift Del 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPG5 | c.1249C>T p.R417* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | catalogued as rs961245497, CM163405, COSV56345253, COSV56352723; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC5 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as rs771605970, COSV55587547; called by muse, varscan2
- ADAMTS6 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.062); catalogued as COSV66857239; called by muse, mutect2, varscan2
- ANKRD37 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52990644; called by muse, varscan2
- C12orf43 | c.292A>T p.I98F | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV56566369; called by muse, mutect2, varscan2
- C7orf57 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.012); catalogued as COSV62361927; called by muse, mutect2
- CCBE1 | c.838G>A p.G280S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs752519349, COSV67949278; called by muse, mutect2, varscan2
- CFAP46 | c.7286-1G>A p.X2429_splice | Splice Site (SNP) | VAF 10/39 reads (26%) | catalogued as COSV54149030; called by muse, mutect2, varscan2
- CT45A10 | c.394A>G p.K132E | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100867560, COSV65921307; called by muse, mutect2, varscan2
- ERCC8 | c.994G>A p.G332S (on ENST00000265038; = p.G313S on NM_000082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as rs764902694, COSV54014669; called by muse, mutect2, varscan2
- GEMIN8 | c.540C>A p.C180* | Nonsense Mutation (SNP) | VAF 16/104 reads (15%) | catalogued as COSV100257138; called by muse, mutect2, varscan2
- HSPBAP1 | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV60241407; called by muse, mutect2, varscan2
- IQCG | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 39/374 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV54560525; called by muse, varscan2
- IRS4 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 34/314 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV64532778; called by muse, mutect2, varscan2
- IZUMO4 | c.320G>C p.R107P | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV61424838, COSV61430627; called by muse, varscan2
- IZUMO4 | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | catalogued as COSV61424847; called by muse, varscan2
- KIF20B | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as rs1484655439, COSV53302895; called by muse, mutect2, varscan2
- MAB21L4 | c.539G>C p.R180T (on ENST00000388934 / NM_001085437.3; = p.R12T on NM_024861.4) | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV56742845; called by muse, mutect2, varscan2
- MAGEC2 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs1419660544, COSV55997966; called by muse, mutect2, varscan2
- MED12 | c.1205C>A p.S402Y | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV61332947; called by muse, mutect2, varscan2
- MUC17 | c.11038G>A p.E3680K | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); catalogued as COSV60281174; called by muse, mutect2, varscan2
- NINL | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs765261480, COSV53999024; called by muse, mutect2, varscan2
- PCDHA2 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.235); catalogued as COSV65365098; called by muse, mutect2, varscan2
- PCDHGB1 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as rs549882944, COSV53905451; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.915); catalogued as COSV51479094; called by muse, mutect2, varscan2
- RFX6 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV60583628; called by muse, mutect2, varscan2
- SBNO1 | c.3050G>A p.G1017E (on ENST00000420886; = p.G1016E on NM_018183.5) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566030220, COSV57339230; called by muse, mutect2, varscan2
- SCN10A | c.1600C>T p.R534W | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs542554745, COSV71860392; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TACO1 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV51975259, COSV51976130; called by muse, mutect2, varscan2
- TIMELESS | c.3451G>A p.E1151K | Missense Mutation (SNP) | VAF 66/236 reads (28%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1251047857, COSV57509247; called by muse, mutect2, varscan2
- TPO | c.2267G>A p.C756Y | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61095971; called by muse, mutect2, varscan2
- TTN | c.85111G>A p.E28371K (on ENST00000591111; = p.E20947K on NM_003319.4) | Missense Mutation (SNP) | VAF 7/12 reads (58%) | PolyPhen probably damaging (0.994); catalogued as rs796978396, COSV59905879; called by muse, mutect2, varscan2
- UBR4 | c.14092C>T p.H4698Y | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.307); catalogued as COSV64383403; called by muse, mutect2, varscan2
- USH2A | c.11900A>G p.D3967G | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56332693; called by muse, mutect2, varscan2
- WDR53 | c.473A>G p.D158G | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376243885, COSV60283628; called by muse, mutect2, varscan2
- ZNF318 | c.1295T>C p.I432T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV58930448; called by muse, mutect2, varscan2
- ZNF329 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs188135790, COSV63771971; called by muse, mutect2, varscan2
- ZNF681 | c.76C>A p.Q26K | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.38); catalogued as COSV101267579; called by muse, mutect2
- CDC5L | c.336del p.N112Kfs*17 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | called by mutect2, pindel, varscan2
- GAS2L2 | c.1112C>G p.S371C | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TACC3 | c.1465_1468dup p.A490Efs*18 | Frame Shift Ins (INS) | VAF 47/212 reads (22%) | called by mutect2, varscan2
- ADCY5 | c.2001C>T p.I667= | Silent (SNP) | VAF 77/403 reads (19%) | catalogued as rs373154919; called by muse, mutect2, varscan2
- CYBB | c.1086A>T p.T362= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV66084828; called by muse, mutect2, varscan2
- DMRT3 | c.1284C>T p.R428= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs764166688, COSV51902493; called by muse, mutect2, varscan2
- GABRG1 | c.552T>A p.I184= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV99778738; called by muse, mutect2
- HELZ2 | c.6987C>T p.F2329= (on ENST00000467148 / NM_001037335.2; = p.F1760= on NM_033405.3) | Silent (SNP) | VAF 53/155 reads (34%) | catalogued as rs561435122, COSV64442508; called by muse, mutect2, varscan2
- HIVEP1 | c.1842C>T p.S614= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV65099061; called by muse, mutect2, varscan2
- IMPG2 | c.2397A>T p.A799= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV51974065; called by muse, mutect2, varscan2
- MS4A6A | c.39G>A p.V13= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV60617033; called by muse, mutect2, varscan2
- PAK5 | c.1395C>T p.I465= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV62021998; called by muse, mutect2, varscan2
- TRPC3 | c.417C>T p.N139= (on ENST00000379645 / NM_001366479.2; = p.N66= on NM_003305.2) | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV53372437; called by muse, mutect2, varscan2
- ZBED1 | c.1815G>T p.L605= | Silent (SNP) | VAF 53/643 reads (8%) | catalogued as COSV100586063; called by muse, mutect2
- C9orf163 | n.1477G>A | RNA (SNP) | VAF 31/88 reads (35%) | called by muse, mutect2, varscan2
- NSD2 | c.1881+2580C>G | Intron (SNP) | VAF 34/110 reads (31%) | catalogued as COSV56387008; called by muse, mutect2, varscan2
